Somatic mutation profile of tumor specimen TCGA-F4-6569-01A (aliquot TCGA-F4-6569-01A-11D-1771-10) from TCGA case TCGA-F4-6569, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.8 years (22,203 days).
Specimen TCGA-F4-6569-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fed8fb5-b7f0-40bc-9fb4-d1827931629f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6569-10A (Blood Derived Normal), aliquot TCGA-F4-6569-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88785112-3f17-4568-bfb0-c213ab6bca25

The open-access MAF lists 130 somatic variants for this specimen: 98 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 29, Nonsense Mutation 10, Frame Shift Ins 3, Intron 3, Frame Shift Del 3, Splice Region 2, Splice Site 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 17/114 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 29/101 reads (29%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.3679C>T p.R1227* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs140021843; called by muse, mutect2, varscan2
- ACTRT2 | c.85T>C p.F29L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV65759652; called by muse, mutect2, varscan2
- ADAMTSL3 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV54454400; called by muse, mutect2, varscan2
- ANKRD44 | c.2348-2A>C p.X783_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99985874; called by muse, mutect2
- ANO5 | c.2541A>C p.K847N | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574225924, COSV61086515; called by muse, mutect2, varscan2
- APC | c.4218del p.S1407Vfs*8 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | catalogued as COSV57332742, COSV57354402, COSV57377402; called by mutect2, pindel, varscan2
- ARHGEF17 | c.1091A>T p.D364V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV99736598; called by muse, mutect2, varscan2
- ARID1A | c.5803G>T p.E1935* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV61375141; called by muse, mutect2, varscan2
- ASB5 | c.588A>C p.Q196H | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as COSV56669600, COSV99641567; called by muse, mutect2
- ASNS | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 17/130 reads (13%) | catalogued as COSV51553415; called by muse, mutect2, varscan2
- ASXL2 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs878904028, COSV55461100; called by muse, mutect2, varscan2
- ATF6 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63408209; called by muse, mutect2, varscan2
- C4orf17 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV58512870; called by muse, mutect2, varscan2
- CD163L1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs770600005, COSV58015212; called by muse, mutect2, varscan2
- CER1 | c.783T>G p.F261L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV66603572; called by muse, mutect2, varscan2
- CHD3 | c.5971C>T p.R1991* (on ENST00000330494 / NM_001005273.3; = p.R1957* on NM_005852.4) | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100177241; called by muse, mutect2, varscan2
- CLK3 | c.1009C>T p.R337C (on ENST00000395066 / NM_001130028.1; = p.R189C on NM_003992.4) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs1185561456, COSV61413673; called by muse, mutect2, varscan2
- CNTN3 | c.1835C>A p.T612K | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV55175386; called by muse, mutect2, varscan2
- CNTN5 | c.2656A>C p.S886R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV54294747, COSV54318234, COSV99678233; called by muse, mutect2
- CNTNAP5 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70472881, COSV70490958; called by muse, mutect2, varscan2
- COL27A1 | c.5359C>T p.R1787C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201559884, COSV61926880; called by muse, mutect2, varscan2
- COL4A5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.5); catalogued as COSV57865205; called by muse, mutect2, varscan2
- CPQ | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV55150198; called by muse, mutect2, varscan2
- CTSF | c.1009T>A p.L337M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV100074469; called by muse, mutect2, varscan2
- DCBLD2 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs763518499, COSV58790245; called by muse, mutect2, varscan2
- DEPDC1 | c.1730T>G p.L577R | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV63958544; called by muse, mutect2, varscan2
- DIP2C | c.4570G>A p.V1524I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs762737938, COSV55147093; called by muse, mutect2, varscan2
- DISP3 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV53828592; called by muse, mutect2, varscan2
- DRG2 | c.541-2A>G p.X181_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56728630; called by muse, mutect2
- DYNC2H1 | c.7385C>A p.S2462Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV62097527; called by muse, mutect2, varscan2
- EPHB4 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as rs1453576486, COSV62269439; called by muse, mutect2, varscan2
- ETNPPL | c.417C>A p.Y139* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV56595568, COSV56596342; called by muse, mutect2, varscan2
- FAM47B | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61454731; called by muse, mutect2, varscan2
- GABRG3 | c.1203A>C p.E401D | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as COSV61522121; called by muse, mutect2
- GATAD2A | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382309211, COSV53067733, COSV99389659; called by muse, mutect2, varscan2
- GCC2 | c.744C>G p.H248Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV59177579; called by muse, mutect2, varscan2
- GDF2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs781951100; called by muse, mutect2, varscan2
- GPR101 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs377596671, COSV99981591; called by muse, mutect2, varscan2
- HSPA12A | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1172828492, COSV65022297; called by muse, mutect2
- IL1R1 | c.359T>G p.L120* | Nonsense Mutation (SNP) | VAF 40/227 reads (18%) | catalogued as COSV52106653; called by muse, mutect2
- IL1RL1 | c.1322G>C p.S441T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52117700; called by muse, mutect2, varscan2
- ITPRID1 | c.1986G>T p.K662N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as COSV60076651; called by muse, mutect2, varscan2
- KCNG1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV65368616; called by muse, mutect2, varscan2
- KIAA0100 | c.5386C>T p.R1796W | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244333409, COSV101197395; called by muse, mutect2, varscan2
- KLHDC8B | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.808); catalogued as rs1052033483, COSV60412119; called by mutect2, varscan2
- KMT2A | c.11102G>A p.R3701Q | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555050212, COSV63283970; called by muse, mutect2, varscan2
- LAMA2 | c.8625dup p.A2876Sfs*30 | Frame Shift Ins (INS) | VAF 21/208 reads (10%) | catalogued as rs749162150; called by mutect2, pindel, varscan2
- LRIF1 | c.2275C>G p.L759V | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63897596; called by muse, mutect2, varscan2
- LRP1B | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV101260043; called by muse, mutect2, varscan2
- LTBP2 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs898615549, COSV56208121; called by muse, mutect2, varscan2
- MAGEB3 | c.691A>G p.R231G | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs1189733701, COSV64397318; called by muse, mutect2, varscan2
- MARCHF4 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56105949, COSV56109409; called by muse, varscan2
- MEF2A | c.1058C>T p.S353L (on ENST00000557942 / NM_001319206.2; = p.S347L on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs748043464, COSV57529610, COSV57534890; called by muse, mutect2, varscan2
- MEF2C | c.1027C>G p.H343D | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.962); catalogued as COSV60933721; called by muse, mutect2, varscan2
- NALCN | c.2497T>G p.F833V | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51944311; called by muse, mutect2
- NBEA | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV59779645; called by muse, mutect2, varscan2
- NCOA3 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs754018637, COSV59070033; called by muse, mutect2, varscan2
- NPY2R | c.556T>G p.F186V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100279875; called by muse, mutect2
- NTNG1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs939752168, COSV53962757; called by muse, mutect2, varscan2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2
- OR51T1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs768466143, COSV59023680; called by muse, mutect2, varscan2
- OR5D13 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV62333075; called by muse, mutect2, varscan2
- OR8H2 | c.813T>A p.D271E | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV57945548; called by muse, mutect2, varscan2
- PAK3 | c.869G>C p.G290A (on ENST00000262836 / NM_001324328.2; = p.G275A on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53276308, COSV53282225; called by muse, mutect2, varscan2
- PCDH18 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100787485, COSV61267206; called by muse, mutect2, varscan2
- PCDHA2 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); catalogued as rs782813610, COSV65364338; called by muse, mutect2, varscan2
- PDGFD | c.771A>C p.K257N | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56382422; called by muse, mutect2
- PPP4R3B | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV55406288; called by muse, mutect2, varscan2
- PTHLH | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 40/186 reads (22%) | catalogued as COSV52367402; called by muse, mutect2, varscan2
- RET | c.2579A>G p.Q860R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100394425; called by muse, mutect2
- RNPEP | c.1206C>T p.G402= | Splice Region (SNP) | VAF 17/80 reads (21%) | catalogued as rs199931910, COSV55238670; called by muse, mutect2, varscan2
- SDK1 | c.2948T>A p.I983N | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67375047; called by muse, mutect2, varscan2
- SIGLEC12 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as rs144207303, COSV99388952; called by muse, mutect2, varscan2
- SPTBN1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.708); catalogued as COSV61689848; called by muse, mutect2, varscan2
- ST7 | c.1310G>T p.G437V (on ENST00000265437 / NM_021908.3; = p.G414V on NM_018412.4) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55387261; called by muse, mutect2, varscan2
- SV2C | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs528331991, COSV59222862; called by muse, mutect2, varscan2
- TASOR | c.1382C>T p.P461L (on ENST00000355628 / NM_001365636.2; = p.P65L on NM_015224.3) | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100843687; called by muse, varscan2
- TCHH | c.5182G>A p.E1728K | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as COSV64275680; called by muse, mutect2
- TDRD5 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 73/392 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54244991; called by muse, mutect2, varscan2
- TEAD1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 84/180 reads (47%) | catalogued as COSV57566406; called by muse, mutect2, varscan2
- TMEM139 | c.241_243del p.A81del | In Frame Del (DEL) | VAF 15/94 reads (16%) | catalogued as COSV60082587; called by mutect2, pindel, varscan2
- TRHDE | c.1975A>C p.I659L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV53850297, COSV53853789; called by muse, mutect2, varscan2
- UGT2B4 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778378649, COSV100522613; called by muse, mutect2, varscan2
- UNC5D | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV54805676, COSV99776562; called by muse, mutect2, varscan2
- UNC5D | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54805693, COSV99776440; called by muse, mutect2, varscan2
- USP35 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1188231380, COSV60868856; called by muse, mutect2, varscan2
- ZFHX4 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs778328088, COSV51449679; called by muse, mutect2, varscan2
- ZNF7 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as rs1347075956, COSV57384220; called by muse, mutect2, varscan2
- DDX60L | c.3615_3622dup p.A1208Vfs*33 | Frame Shift Ins (INS) | VAF 38/274 reads (14%) | called by mutect2, varscan2
- GGA3 | c.2120_2121del p.E707Gfs*34 (on ENST00000537686 / NM_138619.4; = p.E674Gfs*34 on NM_014001.5) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- HADH | c.636+4del | Splice Region (DEL) | VAF 25/137 reads (18%) | called by mutect2, pindel, varscan2
- KLF5 | c.930_932del p.S311del | In Frame Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- MROH1 | c.3718C>G p.P1240A | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC66A1 | c.579_580dup p.L194Cfs*31 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | called by mutect2, pindel
- ZC3H13 | c.1535del p.G512Vfs*23 | Frame Shift Del (DEL) | VAF 43/176 reads (24%) | called by mutect2, pindel, varscan2
- ZNF621 | c.565A>C p.K189Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2
- ABCC1 | c.1797C>G p.L599= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV60681818, COSV60688349; called by muse, mutect2, varscan2
- ACAP2 | c.1047C>T p.R349= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100462638; called by muse, mutect2, varscan2
- ALG9 | c.1590C>T p.I530= (on ENST00000614444 / NM_001352418.1; = p.I537= on NM_024740.2) | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV67644638; called by muse, mutect2, varscan2
- ALX4 | c.927C>T p.L309= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs747416406, COSV100241230, COSV61328400; called by muse, mutect2, varscan2
- ASMT | c.378A>G p.E126= | Silent (SNP) | VAF 37/263 reads (14%) | catalogued as rs1416196178, COSV67109978; called by muse, mutect2, varscan2
- CDH16 | c.315C>T p.V105= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV55337498; called by muse, mutect2, varscan2
- CHST12 | c.993G>A p.P331= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs751420768, COSV51675662; called by mutect2, varscan2
- DHX37 | c.2703C>T p.A901= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs376053916; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1071T>C p.L357= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV100977428; called by muse, mutect2, varscan2
- ETNK2 | c.627C>T p.N209= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs143999368, COSV65820911; called by muse, mutect2, varscan2
- FAT2 | c.3114G>A p.Q1038= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV55822722; called by muse, mutect2, varscan2
- GABRA5 | c.471C>T p.D157= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs764304732, COSV59481433; called by muse, mutect2
- GCC2 | c.2289T>G p.L763= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV59177589; called by muse, mutect2, varscan2
- INPP5B | c.2601G>A p.L867= (on ENST00000373023; = p.L787= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100886597; called by muse, mutect2, varscan2
- LMTK2 | c.3018C>T p.H1006= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs373570191; called by mutect2, varscan2
- NAPEPLD | c.1077G>T p.V359= | Silent (SNP) | VAF 26/355 reads (7%) | catalogued as COSV100085836; called by muse, mutect2
- OSMR | c.630G>T p.G210= | Silent (SNP) | VAF 34/199 reads (17%) | catalogued as COSV57086835, COSV57089250; called by muse, mutect2, varscan2
- PCDHA9 | c.1362G>A p.A454= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as COSV65325237; called by muse, mutect2, varscan2
- PIK3R6 | c.498G>A p.A166= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs1241610853, COSV61003504; called by muse, mutect2, varscan2
- PPP1R12A | c.2049A>G p.K683= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as COSV54110096; called by muse, mutect2, varscan2
- RIMS2 | c.1566G>A p.T522= (on ENST00000666250 / NM_001348490.2; = p.T330= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1157732703, COSV51721068, COSV99192726; called by muse, mutect2, varscan2
- SEMA6B | c.555C>G p.L185= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1310114874, COSV56704458; called by muse, mutect2, varscan2
- SLFN5 | c.1335C>T p.S445= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV55481843; called by muse, mutect2, varscan2
- SORCS1 | c.2208A>T p.R736= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV53876831; called by muse, mutect2, varscan2
- STX11 | c.561C>T p.D187= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV62449555; called by muse, mutect2, varscan2
- TRIM58 | c.1086C>A p.V362= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV63569921; called by muse, mutect2, varscan2
- TSHZ2 | c.1752G>T p.V584= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100296664; called by muse, varscan2
- USH2A | c.9507G>A p.K3169= | Silent (SNP) | VAF 7/159 reads (4%) | catalogued as COSV100233830; called by muse, mutect2
- ZC3H7B | c.30C>T p.I10= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs752066519, COSV60962842; called by muse, mutect2, varscan2
- EEF1D | c.-7-2472G>A | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100415040; called by muse, varscan2
- HDAC9 | c.2577+33T>C | Intron (SNP) | VAF 52/472 reads (11%) | catalogued as COSV67775565; called by muse, mutect2
- TTN | c.10360+2568A>G | Intron (SNP) | VAF 14/72 reads (19%) | catalogued as COSV59950674, COSV60149584; called by muse, mutect2, varscan2
